Somatic mutation profile of tumor specimen TCGA-22-1000-01A (aliquot TCGA-22-1000-01A-01D-1521-08) from TCGA case TCGA-22-1000, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.4 years (27,901 days).
Specimen TCGA-22-1000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b59172b0-4bff-475f-8455-a30ec5bd9c59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1000-11A (Solid Tissue Normal), aliquot TCGA-22-1000-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af72c9e6-347b-4e4e-b579-7a89a793ee1d

The open-access MAF lists 95 somatic variants for this specimen: 71 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Nonsense Mutation 5, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ADAM10 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53052740; called by muse, mutect2, varscan2
- ADAM33 | c.1545G>A p.W515* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100598061; called by muse, mutect2
- ADNP2 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs766821105, COSV51537235; called by muse, mutect2, varscan2
- AICDA | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.67); catalogued as COSV99984347; called by muse, mutect2
- C3AR1 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.361); catalogued as COSV99368914; called by muse, mutect2
- CASC3 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 49/662 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99230002; called by muse, mutect2
- CASC3 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 48/655 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV99230003; called by muse, mutect2
- CEP192 | c.6850A>G p.T2284A | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100381982; called by muse, mutect2
- CLEC4C | c.611C>A p.S204* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | catalogued as COSV100665497; called by muse, mutect2
- COL12A1 | c.4468A>G p.M1490V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1230537277, COSV100486406; called by muse, mutect2
- COL14A1 | c.2059A>T p.T687S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV99920496; called by muse, mutect2
- COLEC11 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV99363620; called by muse, mutect2
- COPS4 | c.254A>T p.Y85F | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as COSV100018818, COSV52313620; called by muse, mutect2
- DGCR2 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.074); catalogued as COSV99593942; called by muse, mutect2
- DIS3L | c.1597G>C p.D533H (on ENST00000319212 / NM_001143688.3; = p.D450H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100055551; called by muse, mutect2, varscan2
- FETUB | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409134; called by muse, mutect2
- FPGT | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100907506; called by muse, mutect2
- HRH2 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99199901; called by muse, mutect2
- IFT140 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV101276609; called by muse, mutect2
- IQCJ | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs747662973, COSV101188772; called by muse, mutect2
- KIF17 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929656; called by muse, mutect2
- KIF2B | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1305227589, COSV52127518, COSV52133387; called by muse, mutect2
- KRT71 | c.279C>G p.C93W | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1325592038, COSV99922381; called by muse, mutect2
- LCP1 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100550059; called by muse, mutect2
- LUZP2 | c.911C>G p.T304S | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV100421196; called by muse, mutect2
- LYSMD3 | c.576A>C p.Q192H | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100270535; called by muse, mutect2
- MAP3K1 | c.1423+1G>C p.X475_splice | Splice Site (SNP) | VAF 16/163 reads (10%) | catalogued as COSV101266817, COSV101267100; called by muse, mutect2
- MAP3K19 | c.254C>G p.T85S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV100209182; called by muse, mutect2, varscan2
- MEGF8 | c.5434G>A p.D1812N (on ENST00000251268 / NM_001271938.2; = p.D1745N on NM_001410.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.752); catalogued as rs747286989, COSV99238778; called by muse, mutect2, varscan2
- MME | c.1498-2A>T p.X500_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100852521; called by muse, mutect2
- MORC1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV99227618, COSV99227663; called by muse, mutect2
- MXRA5 | c.7755G>C p.Q2585H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV99478986; called by muse, mutect2
- NCKAP5L | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV100259171; called by muse, mutect2
- NF2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100099297; called by muse, mutect2
- NOX4 | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV99630811, COSV99631740; called by muse, mutect2
- NPY4R | c.91T>A p.S31T | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as COSV100966215; called by muse, mutect2
- OR2L3 | c.29A>T p.D10V | Missense Mutation (SNP) | VAF 43/627 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100742041; called by muse, mutect2
- OR2M2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 52/504 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62899069, COSV62899483; called by muse, varscan2
- OR4A15 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV59034598, COSV59035155; called by muse, mutect2
- PCDHB14 | c.2191C>G p.P731A | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV53391261, COSV99506226; called by muse, mutect2
- PCDHB14 | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV53391611; called by muse, mutect2
- PDE1C | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776550904, COSV100370811; called by muse, mutect2
- PDE6H | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs868831954, COSV56760417, COSV99844047; called by muse, mutect2
- PGR | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772031832, COSV99679028; called by muse, mutect2
- PROK1 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99602650; called by muse, mutect2
- RAB3GAP2 | c.4093A>G p.I1365V | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100228585; called by muse, mutect2
- RB1 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 41/264 reads (16%) | catalogued as COSV57301410, COSV57303024; called by muse, mutect2, varscan2
- RXFP2 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100034590; called by muse, mutect2
- SELP | c.1596T>G p.Y532* | Nonsense Mutation (SNP) | VAF 14/165 reads (8%) | catalogued as COSV99740991; called by muse, mutect2
- SIPA1L1 | c.315C>G p.C105W | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV100665516; called by muse, mutect2
- SLC22A23 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752326194, COSV100978377; called by muse, mutect2
- SLC45A1 | c.1871C>G p.S624C | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV99239531; called by muse, mutect2
- SMO | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); catalogued as rs1366851376, COSV99977057; called by muse, mutect2
- SPATA31E1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.794); catalogued as COSV100351001; called by muse, mutect2, varscan2
- SSR3 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99411220; called by muse, mutect2
- TGM4 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99942599; called by muse, mutect2
- THNSL1 | c.1883T>G p.I628S | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100896298; called by muse, mutect2, varscan2
- TMCC1 | c.933G>C p.Q311H | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100261262; called by muse, mutect2
- TNRC6C | c.3937G>T p.A1313S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV100050597; called by muse, mutect2, varscan2
- TRIO | c.4954G>T p.D1652Y | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100710889; called by muse, mutect2, varscan2
- TTN | c.9865C>A p.H3289N (on ENST00000591111; = p.H3243N on NM_003319.4) | Missense Mutation (SNP) | VAF 30/302 reads (10%) | PolyPhen benign (0.415); catalogued as COSV100627604, COSV59863902; called by muse, mutect2, varscan2
- UTP20 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.164); catalogued as COSV99882452; called by muse, mutect2
- VPS35 | c.1290C>G p.Y430* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV100140777; called by muse, mutect2
- ZNF236 | c.4021G>T p.A1341S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV99471132; called by muse, mutect2
- ZXDA | c.1183G>C p.G395R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs45580541, COSV100699464; called by muse, mutect2, varscan2
- ASPM | c.8461dup p.I2821Nfs*7 | Frame Shift Ins (INS) | VAF 20/223 reads (9%) | called by mutect2, pindel
- EPHA2 | c.937_954del p.F313_Q318del | In Frame Del (DEL) | VAF 3/39 reads (8%) | called by mutect2, pindel*
- IGKV1D-33 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC35F4 | c.1196C>A p.P399Q (on ENST00000339762 / NM_001352015.2; = p.P363Q on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by mutect2, varscan2
- TRGV8 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.749); called by muse, mutect2
- ADGRL3 | c.3954G>A p.L1318= (on ENST00000506720 / NM_001322402.2; = p.L1207= on NM_015236.6) | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV101541156; called by muse, mutect2
- ASB5 | c.561G>T p.L187= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as COSV99642052; called by muse, mutect2
- CCDC91 | c.153G>T p.L51= | Silent (SNP) | VAF 38/476 reads (8%) | catalogued as rs141221873; called by muse, mutect2
- CHRNB2 | c.126C>T p.Y42= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV100872668; called by muse, mutect2
- CPB1 | c.691C>A p.R231= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV51572540, COSV99294472; called by muse, mutect2
- GRIA4 | c.318G>A p.L106= | Silent (SNP) | VAF 17/185 reads (9%) | catalogued as rs1024262623, COSV56911324, COSV99234165; called by muse, mutect2
- GRM3 | c.780C>A p.I260= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100862840, COSV64476925; called by muse, mutect2
- GSPT2 | c.1623G>T p.A541= | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as rs1557348993; called by muse, mutect2
- IFT140 | c.474G>T p.R158= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as rs145287241; called by muse, mutect2
- IPO13 | c.2676G>A p.L892= | Silent (SNP) | VAF 13/208 reads (6%) | catalogued as COSV99664712; called by muse, mutect2
- MICAL1 | c.2901G>A p.K967= | Silent (SNP) | VAF 20/266 reads (8%) | catalogued as COSV57804316, COSV99238141; called by muse, mutect2
- NAT2 | c.738T>C p.Y246= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV99674187; called by muse, mutect2, varscan2
- OR51G1 | c.150C>T p.V50= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100429401; called by muse, mutect2, varscan2
- OR5C1 | c.850C>T p.L284= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV101030604; called by muse, mutect2, varscan2
- PCDHA3 | c.144C>T p.I48= | Silent (SNP) | VAF 21/207 reads (10%) | catalogued as rs782016888, COSV65365985, COSV65369479, COSV65370196; called by muse, mutect2, varscan2
- PCDHGA5 | c.1648C>T p.L550= | Silent (SNP) | VAF 34/388 reads (9%) | catalogued as COSV53949128, COSV99545969; called by muse, mutect2
- PLEKHA7 | c.2592A>T p.P864= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as COSV100262001; called by muse, mutect2
- SLC26A1 | c.486C>G p.L162= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99926407; called by muse, mutect2
- SLC36A4 | c.276A>G p.G92= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV100419456; called by muse, mutect2
- TLDC2 | c.268C>T p.L90= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV99456171; called by muse, mutect2
- TRIML2 | c.1173C>T p.L391= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as COSV100456316; called by muse, mutect2
- TSPEAR | c.267C>T p.I89= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs782010486, COSV59962692; called by muse, varscan2
- ZNF792 | c.786C>G p.A262= | Silent (SNP) | VAF 13/188 reads (7%) | catalogued as COSV101289755; called by muse, mutect2
- CIT | c.2082+1953C>T | Intron (SNP) | VAF 18/162 reads (11%) | catalogued as COSV99950798; called by muse, mutect2, varscan2
